Somatic mutation profile of tumor specimen ALCH-B0GU-TTP1-A (aliquot ALCH-B0GU-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0GU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 48.8 years (17,827 days).
Specimen ALCH-B0GU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af31e1b6-5d16-475c-93ef-8bf062cf9571.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0GU-NB1-A (Blood Derived Normal), aliquot ALCH-B0GU-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bdfafb7-61b1-4c01-b3f5-95cec9b7f7ba

The open-access MAF lists 214 somatic variants for this specimen: 151 protein-altering or splice-affecting, 35 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 35, Intron 13, RNA 6, Nonsense Mutation 5, 5'UTR 4, 5'Flank 3, Splice Site 2, Frame Shift Del 2, 3'Flank 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 144/243 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.842del p.P281Rfs*6 | Frame Shift Del (DEL) | VAF 43/84 reads (51%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANK2 | c.8725C>G p.P2909A | Missense Mutation (SNP) | VAF 135/596 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.443); catalogued as COSV52162583; called by muse, varscan2
- ASXL3 | c.5475C>A p.N1825K | Missense Mutation (SNP) | VAF 141/596 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as rs773589470; called by muse, mutect2, varscan2
- ATF6 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs756079770; called by muse, varscan2
- B3GNT2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV57345622; called by muse, mutect2, varscan2
- BICC1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1332827341, COSV65857430; called by muse, mutect2
- BRINP3 | c.1668G>T p.Q556H | Missense Mutation (SNP) | VAF 158/472 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV66517308; called by muse, mutect2, varscan2
- CCDC141 | c.4414T>C p.C1472R | Missense Mutation (SNP) | VAF 118/500 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs569278815; called by muse, mutect2, varscan2
- CFHR4 | c.1304G>T p.G435V (on ENST00000367416 / NM_001201551.2; = p.G189V on NM_006684.5) | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV52227197; called by muse, mutect2, varscan2
- CLIC5 | c.983A>T p.K328M (on ENST00000185206 / NM_001370649.1; = p.K169M on NM_016929.5) | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV99483509; called by muse, mutect2, varscan2
- CSMD3 | c.7162C>A p.H2388N (on ENST00000297405 / NM_001363185.1; = p.H2284N on NM_052900.3) | Missense Mutation (SNP) | VAF 142/506 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as rs1328025055, COSV52264776, COSV52291109; called by muse, mutect2, varscan2
- CTRC | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.131); catalogued as rs775404479, CM080171; called by muse, mutect2, varscan2
- DCAF8L1 | c.1384G>C p.V462L | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV71595154, COSV71595188; called by muse, mutect2, varscan2
- DCDC1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV60839592, COSV60860485; called by muse, mutect2, varscan2
- DNAH7 | c.1100T>G p.L367R | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100413525, COSV56755783; called by muse, mutect2, varscan2
- ELAVL2 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 76/436 reads (17%) | catalogued as COSV99806413; called by muse, varscan2
- FAM178B | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs770825809, COSV59971962, COSV59972206; called by muse, mutect2, varscan2
- FSCB | c.2143G>T p.D715Y | Missense Mutation (SNP) | VAF 185/491 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1489346073; called by muse, mutect2, varscan2
- GEMIN8 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 270/522 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV60550146; called by muse, mutect2, varscan2
- GJD4 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 147/369 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.586); catalogued as COSV58703614; called by muse, mutect2, varscan2
- GLRA1 | c.1352G>A p.R451K (on ENST00000455880 / NM_001146040.2; = p.R443K on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/344 reads (51%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.071); catalogued as rs1415816176; called by muse, mutect2, varscan2
- GPR158 | c.2067G>T p.M689I | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV66286291; called by muse, mutect2, varscan2
- GSG1L | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 140/437 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1338511209; called by muse, mutect2, varscan2
- KIFC2 | c.285G>C p.Q95H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as rs1025194769; called by muse, mutect2, varscan2
- KRT1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1438038973, COSV99358545; called by muse, mutect2, varscan2
- LRRC4B | c.737C>A p.P246Q | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV65350908; called by muse, mutect2, varscan2
- MTNR1B | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 292/436 reads (67%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs149192012; called by muse, mutect2, varscan2
- NEK2 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1372194983, COSV65355244; called by muse, mutect2
- NOS1 | c.2013C>A p.Y671* | Nonsense Mutation (SNP) | VAF 42/176 reads (24%) | catalogued as rs757310877, COSV57618426; called by muse, varscan2
- NXF1 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.242); catalogued as rs780115078, COSV53672884, COSV99585658; called by muse, mutect2, varscan2
- OPN1SW | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 187/343 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs765180645; called by muse, mutect2, varscan2
- OR14K1 | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 255/671 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs367970677, COSV99314974; called by muse, mutect2, varscan2
- OR4Q3 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV59178100, COSV59179076; called by muse, mutect2, varscan2
- OR51G1 | c.445A>C p.S149R | Missense Mutation (SNP) | VAF 26/726 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV58968526, COSV58971231; called by muse, mutect2
- OR5AP2 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV57257035; called by muse, mutect2, varscan2
- OR6V1 | c.530G>C p.C177S | Missense Mutation (SNP) | VAF 132/479 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69237503; called by muse, mutect2, varscan2
- PABPC5 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1050568530; called by muse, mutect2
- PCDHA7 | c.1412del p.G471Afs*65 | Frame Shift Del (DEL) | VAF 297/617 reads (48%) | catalogued as COSV100971989; called by mutect2, pindel, varscan2
- PCDHGA2 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 100/180 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV53937516, COSV53940629; called by muse, mutect2, varscan2
- PDE4D | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 138/396 reads (35%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs764578237; called by muse, mutect2, varscan2
- PHKA2 | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 251/468 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66052144; called by muse, mutect2, varscan2
- PIK3R6 | c.776T>A p.L259Q | Missense Mutation (SNP) | VAF 150/517 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs931178955; called by muse, mutect2, varscan2
- POM121L2 | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 153/308 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66276874; called by muse, mutect2, varscan2
- POTEB3 | c.913G>T p.G305* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs1327015062; called by mutect2, varscan2
- RASGRP4 | c.1496C>A p.P499H | Missense Mutation (SNP) | VAF 168/522 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53039227, COSV53040205; called by mutect2, varscan2
- RTN1 | c.1529C>A p.A510E | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as COSV50718474; called by muse, mutect2
- SCAF11 | c.2861T>C p.F954S | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1219628635; called by muse, mutect2, varscan2
- SGSM3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139798144; called by muse, mutect2, varscan2
- SON | c.697A>G p.M233V | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as rs764589154; called by muse, mutect2, varscan2
- SYN2 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV70286756; called by muse, mutect2, varscan2
- TASOR2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.072); catalogued as rs1247934672; called by muse, mutect2
- TCF4 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 235/706 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61891254; called by muse, mutect2, varscan2
- TRIM58 | c.623A>G p.E208G | Missense Mutation (SNP) | VAF 378/986 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs765037452; called by muse, mutect2, varscan2
- TTLL8 | c.2357G>T p.R786L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV56723192; called by muse, mutect2, varscan2
- TTN | c.54935C>T p.A18312V (on ENST00000591111; = p.A10888V on NM_003319.4) | Missense Mutation (SNP) | VAF 62/335 reads (19%) | PolyPhen possibly damaging (0.823); catalogued as rs754149259, COSV100625874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.2937G>T p.Q979H | Missense Mutation (SNP) | VAF 139/413 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100663944; called by muse, mutect2, varscan2
- VWC2L | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.813); catalogued as rs1453560172; called by muse, mutect2, varscan2
- WDR11 | c.1703A>C p.E568A | Missense Mutation (SNP) | VAF 217/461 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99676452; called by muse, mutect2, varscan2
- ZNF536 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 359/1075 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100834501; called by muse, mutect2, varscan2
- ZNF607 | c.1940G>T p.C647F | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757568454; called by muse, mutect2, varscan2
- ZNF607 | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV67696347; called by muse, mutect2, varscan2
- ACER1 | c.481T>A p.Y161N | Missense Mutation (SNP) | VAF 105/203 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ADA2 | c.104C>A p.A35E | Missense Mutation (SNP) | VAF 183/595 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM7 | c.1274C>A p.T425N | Missense Mutation (SNP) | VAF 100/151 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGB | c.1353C>A p.H451Q | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ALDH1A2 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 61/334 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ANKRD50 | c.1358A>T p.Q453L | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ARF5 | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 70/108 reads (65%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- BHLHA9 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BHMG1 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BRINP3 | c.1873G>C p.V625L | Missense Mutation (SNP) | VAF 92/684 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C16orf78 | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CBLB | c.729G>T p.W243C | Missense Mutation (SNP) | VAF 107/219 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCM2L | c.1352G>T p.C451F (on ENST00000452892 / NM_001365692.1; = p.A430S on NM_080625.4) | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD7 | c.3520C>T p.Q1174* | Nonsense Mutation (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- CNGA3 | c.579T>A p.D193E | Missense Mutation (SNP) | VAF 194/652 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CNP | c.590A>C p.K197T | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CORO6 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CPNE5 | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 246/487 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DEFB108B | c.42G>A p.M14I | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DEFB123 | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLAT | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 134/243 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DNAH6 | c.8321A>T p.D2774V | Missense Mutation (SNP) | VAF 196/539 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- EPYC | c.741C>A p.N247K | Missense Mutation (SNP) | VAF 136/474 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM135B | c.2969C>A p.T990N | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM186A | c.5855C>T p.A1952V | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN2 | c.6844G>A p.G2282S | Missense Mutation (SNP) | VAF 150/278 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- FTSJ1 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 205/393 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GALNTL6 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GCNT1 | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 124/201 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPX5 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GUF1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2
- HAS1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 88/528 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.072); called by muse, varscan2
- HAUS5 | c.1478T>A p.F493Y | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC9 | c.578G>C p.S193T | Missense Mutation (SNP) | VAF 142/268 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.092); called by muse, varscan2
- HERC6 | c.2885A>T p.Q962L | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- HGF | c.1010A>T p.H337L | Missense Mutation (SNP) | VAF 134/265 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMCN1 | c.2483G>T p.R828I | Missense Mutation (SNP) | VAF 152/400 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, varscan2
- ITGAM | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 185/584 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KCNA5 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 134/492 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- KEL | c.1661C>G p.A554G | Missense Mutation (SNP) | VAF 190/379 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- LMX1A | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTB4R | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MACF1 | c.19233G>T p.Q6411H (on ENST00000372915; = p.Q4456H on NM_012090.5) | Missense Mutation (SNP) | VAF 44/230 reads (19%) | called by muse, mutect2, varscan2
- MACF1 | c.19234A>T p.S6412C (on ENST00000372915; = p.S4457C on NM_012090.5) | Missense Mutation (SNP) | VAF 40/226 reads (18%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1930C>A p.Q644K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K6 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCHR2 | c.183-1G>T p.X61_splice | Splice Site (SNP) | VAF 22/86 reads (26%) | called by muse, varscan2
- MDC1 | c.6185C>T p.P2062L | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- MED12L | c.3551T>C p.M1184T | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MIGA1 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MOAP1 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NEDD4L | c.1783A>G p.R595G (on ENST00000400345 / NM_001144967.3; = p.R575G on NM_015277.6) | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- NTSR1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2AJ1 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- OTOF | c.3734-1G>C p.X1245_splice | Splice Site (SNP) | VAF 252/649 reads (39%) | called by muse, mutect2, varscan2
- OVCH1 | c.2528C>A p.P843Q | Missense Mutation (SNP) | VAF 130/232 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- P2RX7 | c.1202T>G p.V401G | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PIKFYVE | c.525G>T p.R175S | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PODN | c.1195C>A p.H399N (on ENST00000395871; = p.H351N on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- POLI | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2
- PRAMEF27 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.297); called by mutect2, varscan2
- RHAG | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 423/941 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTTN | c.4234G>T p.G1412C | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEPTIN14 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 74/126 reads (59%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC24A3 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 108/327 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC44A5 | c.1399C>G p.L467V | Missense Mutation (SNP) | VAF 96/439 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- SMIM32 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SPRR3 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- STARD9 | c.7877G>T p.G2626V | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SULT2A1 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 137/403 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TBC1D17 | c.1430T>C p.L477P | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- TENM2 | c.1129G>C p.A377P (on ENST00000518659 / NM_001122679.2; = p.A186P on NM_001080428.3) | Missense Mutation (SNP) | VAF 133/245 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX47 | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 96/171 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, varscan2
- TF | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 324/595 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- TGFBR1 | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 114/210 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- TMEM232 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- TMEM72 | c.138-3C>G | Splice Region (SNP) | VAF 51/341 reads (15%) | called by muse, mutect2, varscan2
- TPBG | c.143T>A p.L48Q | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TRANK1 | c.8699A>T p.Y2900F | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TSPAN11 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 165/284 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- TSPOAP1 | c.1491G>T p.M497I | Missense Mutation (SNP) | VAF 205/640 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- URI1 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VPS13C | c.5783T>A p.L1928H (on ENST00000644861 / NM_020821.3; = p.L1885H on NM_017684.5) | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- WDR74 | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 316/622 reads (51%) | called by muse, mutect2, varscan2
- ZNF431 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF551 | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 63/484 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ZNF613 | c.187G>A p.G63R (on ENST00000293471 / NM_001031721.4; = p.G27R on NM_024840.4) | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF99 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZZEF1 | c.6820A>T p.I2274F | Missense Mutation (SNP) | VAF 116/354 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- AC127029.3 | c.858G>A p.R286= | Silent (SNP) | VAF 275/962 reads (29%) | catalogued as COSV60112051; called by muse, mutect2, varscan2
- ACSM2A | c.1209C>A p.P403= (on ENST00000219054; = p.P324= on NM_001308169.2) | Silent (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- ADH1C | c.603G>C p.L201= | Silent (SNP) | VAF 56/177 reads (32%) | called by muse, mutect2, varscan2
- ADORA2B | c.465A>T p.T155= | Silent (SNP) | VAF 131/381 reads (34%) | called by muse, mutect2, varscan2
- ATP11C | c.1728G>T p.V576= | Silent (SNP) | VAF 55/119 reads (46%) | called by muse, mutect2, varscan2
- B4GALT3 | c.1068T>A p.R356= | Silent (SNP) | VAF 338/959 reads (35%) | catalogued as COSV100157814; called by muse, mutect2, varscan2
- BID | c.144C>T p.D48= (on ENST00000317361 / NM_197966.2; = p.D2= on NM_001196.4) | Silent (SNP) | VAF 113/312 reads (36%) | catalogued as rs200037829; called by muse, mutect2, varscan2
- CACNG4 | c.336C>A p.I112= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV50926103; called by muse, mutect2, varscan2
- CHRNA7 | c.606C>A p.P202= | Silent (SNP) | VAF 134/381 reads (35%) | catalogued as rs202234032; called by muse, mutect2, varscan2
- FAM222B | c.645T>G p.A215= | Silent (SNP) | VAF 48/307 reads (16%) | called by muse, mutect2, varscan2
- GSK3B | c.393G>T p.V131= | Silent (SNP) | VAF 83/168 reads (49%) | called by muse, mutect2, varscan2
- HSD3B2 | c.204G>T p.L68= | Silent (SNP) | VAF 133/616 reads (22%) | called by muse, mutect2, varscan2
- IP6K3 | c.660C>A p.T220= | Silent (SNP) | VAF 38/358 reads (11%) | catalogued as COSV53391753; called by muse, varscan2
- KLK5 | c.537C>T p.P179= | Silent (SNP) | VAF 212/541 reads (39%) | catalogued as rs1384609300, COSV60451064; called by muse, mutect2, varscan2
- MAMSTR | c.39T>C p.I13= | Silent (SNP) | VAF 40/610 reads (7%) | called by muse, mutect2
- MUC2 | c.2926C>A p.R976= | Silent (SNP) | VAF 81/161 reads (50%) | called by muse, mutect2, varscan2
- MYO7A | c.4242C>T p.P1414= | Silent (SNP) | VAF 180/281 reads (64%) | catalogued as rs1297093744; called by muse, mutect2, varscan2
- OR10A4 | c.231C>A p.V77= | Silent (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2, varscan2
- OR13F1 | c.339G>T p.V113= | Silent (SNP) | VAF 47/148 reads (32%) | catalogued as rs182853745; called by muse, mutect2, varscan2
- OR6K6 | c.942C>T p.P314= (on ENST00000368144; = p.P290= on NM_001005184.1) | Silent (SNP) | VAF 63/279 reads (23%) | called by muse, mutect2, varscan2
- PHF14 | c.570A>T p.P190= | Silent (SNP) | VAF 90/159 reads (57%) | called by muse, mutect2, varscan2
- RAB3B | c.253C>A p.R85= | Silent (SNP) | VAF 38/157 reads (24%) | catalogued as COSV65434345; called by muse, mutect2, varscan2
- RNASE3 | c.132T>C p.S44= | Silent (SNP) | VAF 232/622 reads (37%) | called by muse, mutect2, varscan2
- RYR1 | c.936C>A p.S312= | Silent (SNP) | VAF 264/799 reads (33%) | called by muse, mutect2, varscan2
- SERPINA12 | c.1128G>T p.L376= | Silent (SNP) | VAF 48/330 reads (15%) | called by muse, mutect2, varscan2
- SLITRK2 | c.2284C>A p.R762= | Silent (SNP) | VAF 107/191 reads (56%) | catalogued as COSV59427015; called by muse, mutect2, varscan2
- SNED1 | c.459C>T p.T153= | Silent (SNP) | VAF 82/210 reads (39%) | called by muse, mutect2, varscan2
- SNTB1 | c.594G>A p.T198= | Silent (SNP) | VAF 65/361 reads (18%) | catalogued as rs1164263344, COSV67325887; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1476A>G p.P492= | Silent (SNP) | VAF 564/1018 reads (55%) | called by mutect2, varscan2
- TDRD9 | c.2676C>T p.S892= | Silent (SNP) | VAF 79/288 reads (27%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.283C>A p.R95= | Silent (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- TNR | c.738G>T p.V246= | Silent (SNP) | VAF 157/423 reads (37%) | called by muse, mutect2, varscan2
- TRPM3 | c.243C>A p.P81= (on ENST00000357533 / NM_001366142.2; = p.P50= on NM_001007471.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- UBXN10 | c.324C>T p.S108= | Silent (SNP) | VAF 83/300 reads (28%) | called by muse, mutect2, varscan2
- USHBP1 | c.1701T>G p.P567= | Silent (SNP) | VAF 169/296 reads (57%) | catalogued as rs560671164; called by muse, mutect2, varscan2
- AC107023.1 | n.25+1904G>T | Intron (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27195945 C>G | 3'Flank (SNP) | VAF 13/149 reads (9%) | catalogued as rs1475586677; called by muse, mutect2
- ANKS1B | c.3672+5579G>A | Intron (SNP) | VAF 128/436 reads (29%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501471 del CAGACTTTAAAAGTGCTTA | 5'Flank (DEL) | VAF 30/178 reads (17%) | called by mutect2, pindel, varscan2
- BSG | c.416-523G>T | Intron (SNP) | VAF 48/80 reads (60%) | called by muse, mutect2, varscan2
- CLEC4A | c.299-878G>T | Intron (SNP) | VAF 39/296 reads (13%) | called by muse, mutect2, varscan2
- CST9LP1 | n.207G>C | RNA (SNP) | VAF 49/109 reads (45%) | called by muse, mutect2, varscan2
- GPR26 | c.-12G>T | 5'UTR (SNP) | VAF 10/32 reads (31%) | called by muse, varscan2
- IGFN1 | c.1241+806G>T | Intron (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.-8G>C | 5'UTR (SNP) | VAF 136/575 reads (24%) | called by muse, mutect2, varscan2
- LIM2 | c.175+58G>T | Intron (SNP) | VAF 150/433 reads (35%) | called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.-493+11458C>A | Intron (SNP) | VAF 119/454 reads (26%) | called by muse, mutect2, varscan2
- MOB2 | chr11:1469767 C>A | 3'Flank (SNP) | VAF 124/252 reads (49%) | catalogued as rs914106669; called by muse, mutect2, varscan2
- NUDT4 | chr12:93377499 A>G | 5'Flank (SNP) | VAF 44/452 reads (10%) | called by muse, mutect2
- OR2A13P | n.545C>G | RNA (SNP) | VAF 112/219 reads (51%) | called by muse, mutect2, varscan2
- OR56B3P | n.733C>G | RNA (SNP) | VAF 104/309 reads (34%) | called by muse, varscan2
- PDZD7 | c.-110G>T | 5'UTR (SNP) | VAF 93/227 reads (41%) | called by muse, mutect2, varscan2
- PTPA | chr9:129111051 C>A | 5'Flank (SNP) | VAF 173/328 reads (53%) | called by muse, mutect2, varscan2
- RBM39 | c.101+2377C>T | Intron (SNP) | VAF 23/147 reads (16%) | catalogued as rs911111233, COSV53614644; called by muse, mutect2, varscan2
- RNF213 | c.3024+172_3024+175del | Intron (DEL) | VAF 60/359 reads (17%) | called by mutect2, pindel, varscan2
- SMPD4BP | n.2256A>G | RNA (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- SPATA8 | n.800G>T | RNA (SNP) | VAF 187/374 reads (50%) | catalogued as COSV100139158, COSV60705116; called by muse, mutect2, varscan2
- SVIL2P | n.1790G>A | RNA (SNP) | VAF 183/407 reads (45%) | called by muse, mutect2, varscan2
- TDRD5 | c.2160+2004C>A | Intron (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2
- TRPM3 | c.979+16660G>T | Intron (SNP) | VAF 54/205 reads (26%) | called by muse, varscan2
- UROD | c.774+47A>T | Intron (SNP) | VAF 73/443 reads (16%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-411G>T | Intron (SNP) | VAF 44/133 reads (33%) | called by muse, mutect2, varscan2
- ZNF773 | c.-54C>A | 5'UTR (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
